Somatic mutation profile of tumor specimen 0DPBGA from CCDI case PBCDNM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.9 years (2,142 days).
Specimen 0DPBGA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a31faf7-7421-4ccc-bcbd-6fea2741d58e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBFF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35c867ce-4796-4053-9a1c-743898eb5b00

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRE | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 40/694 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV64819874; called by muse, mutect2
- DAGLA | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 164/493 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ACSF3 | c.300C>T p.F100= | Silent (SNP) | VAF 39/375 reads (10%) | called by muse, mutect2, varscan2
- HMGB3 | c.486G>A p.S162= | Silent (SNP) | VAF 169/788 reads (21%) | catalogued as rs782588935, COSV57486023; called by muse, mutect2, varscan2
